Surgical pathology report (de-identified scan), TCGA case TCGA-G2-A3IB, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-A3IB-01A (Primary Tumor).

DIAGNOSIS

(A) BLADDER TUMOR:

UROTHELIAL CARCINOMA, HIGH GRADE WITH EXTENSIVE SQUAMOUS DIFFERENTIATION (GREATER THAN 50%).

TUMOR INVADES THE MUSCULARIS PROPRIA.
POSITIVE FOR LYMPHOVASCULAR INVASION.

(B) PROSTATIC URETHRA:

Benign prostatic urethra with chronic inflammation and reactive changes.
Benign prostatic glands and fibromuscular stroma also noted.

GROSS DESCRIPTION

(A) BLADDER TUMOR – Multiple irregular fragments of white-tan soft tissue (2.0 x 2.0 x 1.0 cm in aggregate). Entirely submitted in A1-A3.

(B) PROSTATIC URETHRA – Two irregular fragments of white-tan soft tissue (0.5 x 0.4 x 0.3 cm each). Entirely submitted in B.

CLINICAL HISTORY

Bladder cancer.

ICD-0-3
carcinoma, urothelial, NOS 8120/3
Site: bladder, NOS C67.9 ju
12/8/11

Source: NCI Genomic Data Commons file 4c746916-8026-415c-98c8-cac1dd976d92 (TCGA-G2-A3IB.AD5273EB-8A12-4000-A0EB-99CED937D6D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).